Somatic mutation profile of tumor specimen TCGA-60-2695-01A (aliquot TCGA-60-2695-01A-01D-1522-08) from TCGA case TCGA-60-2695, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.5 years (27,211 days).
Specimen TCGA-60-2695-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b728883-04ce-463e-91e9-0435db59a991.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2695-11A (Solid Tissue Normal), aliquot TCGA-60-2695-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9829086e-47c1-455f-9477-b66bc58a813d

The open-access MAF lists 202 somatic variants for this specimen: 163 protein-altering or splice-affecting, 37 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 37, Nonsense Mutation 11, Frame Shift Del 5, Splice Site 3, Frame Shift Ins 2, Translation Start Site 2, Intron 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 49/185 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 37/44 reads (84%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB7 | c.988G>C p.G330R (on ENST00000373394 / NM_001271696.3; = p.G331R on NM_004299.6) | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV53721135, COSV99504627; called by muse, mutect2, varscan2
- ABCG2 | c.1915A>G p.I639V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV99419732; called by muse, mutect2, varscan2
- AC136428.1 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as COSV101434978; called by muse, mutect2, varscan2
- ADAMTS3 | c.2162G>T p.R721I | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54393276, COSV99711689; called by muse, mutect2, varscan2
- ADCY9 | c.2851G>C p.D951H | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.215); catalogued as COSV99570494; called by muse, mutect2
- ADGRA3 | c.1729C>G p.R577G | Missense Mutation (SNP) | VAF 135/343 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.982); catalogued as COSV99293574; called by muse, mutect2, varscan2
- ADGRE3 | c.1174C>A p.H392N | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV99506485; called by muse, mutect2, varscan2
- AGAP2 | c.1953+1G>A p.X651_splice (on ENST00000547588 / NM_001122772.2; = p.X315_splice on NM_014770.4) | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as rs1217085589, COSV99223820; called by muse, mutect2, varscan2
- AKAP9 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | catalogued as COSV100662745; called by muse, mutect2
- ALPP | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763781524, COSV101235168; called by muse, mutect2, varscan2
- ARHGEF1 | c.504G>T p.W168C | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV100529126; called by muse, mutect2
- ARHGEF11 | c.2956G>T p.V986L | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV100168813; called by muse, mutect2, varscan2
- ARHGEF6 | c.2245C>A p.L749I | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV99166586; called by muse, mutect2, varscan2
- ASTN1 | c.1973G>T p.G658V | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56067429, COSV99922544; called by muse, mutect2, varscan2
- ATP1B1 | c.897T>G p.I299M | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.442); catalogued as COSV100891116; called by muse, mutect2, varscan2
- BBX | c.2487A>C p.K829N (on ENST00000325805 / NM_001142568.3; = p.K799N on NM_020235.7) | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100362043; called by muse, mutect2, varscan2
- BEST2 | c.949-2A>T p.X317_splice | Splice Site (SNP) | VAF 72/262 reads (27%) | catalogued as COSV99244571; called by mutect2, varscan2
- BMX | c.77A>T p.Y26F | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as COSV100564579; called by muse, mutect2, varscan2
- C2orf16 | c.3724T>A p.L1242I | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.236); catalogued as COSV100820898; called by muse, mutect2, varscan2
- CACNA1S | c.1730del p.G577Afs*35 | Frame Shift Del (DEL) | VAF 44/209 reads (21%) | catalogued as COSV62935588; called by mutect2, pindel, varscan2
- CALCR | c.220C>A p.R74S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100810718; called by muse, mutect2, varscan2
- CALM1 | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 98/280 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV100811163; called by muse, mutect2, varscan2
- CALN1 | c.41G>T p.G14V (on ENST00000329008 / NM_001017440.3; = p.G56V on NM_031468.4) | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100208327; called by muse, mutect2, varscan2
- CALN1 | c.40G>T p.G14W (on ENST00000329008 / NM_001017440.3; = p.G56W on NM_031468.4) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100205157, COSV61149726; called by muse, mutect2, varscan2
- CCDC150 | c.2685A>T p.Q895H | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99777192; called by muse, mutect2, varscan2
- CCDC81 | c.1429A>T p.M477L (on ENST00000445632 / NM_001156474.2; = p.M387L on NM_021827.4) | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV99564643; called by muse, mutect2, varscan2
- CMBL | c.23G>T p.C8F | Missense Mutation (SNP) | VAF 80/315 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV99687170; called by muse, varscan2
- CSMD1 | c.10168T>G p.F3390V (on ENST00000520002; = p.F3389V on NM_033225.6) | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV100151532; called by muse, mutect2, varscan2
- CYBB | c.117C>G p.F39L | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV101059796, COSV66084945, COSV66085645; called by muse, mutect2, varscan2
- CYLC2 | c.696A>G p.I232M | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100872514; called by muse, mutect2, varscan2
- CYP1A2 | c.1376T>G p.I459S | Missense Mutation (SNP) | VAF 97/161 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100673919; called by muse, mutect2, varscan2
- CYP2C19 | c.613A>T p.I205F | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100990584; called by muse, mutect2, varscan2
- DAPK3 | c.426G>C p.P142= | Splice Region (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100009811; called by muse, mutect2, varscan2
- DBNDD1 | c.76C>G p.P26A (on ENST00000002501 / NM_001042610.3; = p.P46A on NM_024043.3) | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.098); catalogued as COSV99136540; called by muse, mutect2, varscan2
- DCAF12L1 | c.1064C>A p.S355* | Nonsense Mutation (SNP) | VAF 36/73 reads (49%) | catalogued as COSV100948387; called by muse, mutect2, varscan2
- DDI1 | c.132G>C p.E44D | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as COSV100160153, COSV56388047; called by muse, mutect2, varscan2
- DLC1 | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 146/169 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs779862909, COSV99364487; called by muse, mutect2, varscan2
- DLG3 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99529876; called by muse, mutect2, varscan2
- DLK1 | c.619C>A p.R207S | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.946); catalogued as COSV100375349, COSV57991368; called by muse, mutect2, varscan2
- DNAH7 | c.3919A>G p.T1307A | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100416439; called by muse, mutect2, varscan2
- DOCK4 | c.2827G>T p.E943* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV101447919; called by muse, mutect2, varscan2
- DOK3 | c.1043T>A p.L348Q | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV100467261; called by muse, mutect2, varscan2
- DSG3 | c.1108G>T p.V370F | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV99934512; called by muse, mutect2, varscan2
- ECRG4 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99430445; called by muse, mutect2
- EGFLAM | c.1121G>A p.G374D | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59294519; called by muse, mutect2, varscan2
- EIF2AK4 | c.4567T>C p.F1523L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV99775108; called by muse, mutect2, varscan2
- FAM133A | c.52A>G p.R18G | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100220536; called by muse, mutect2, varscan2
- FMR1 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs1272102686, COSV54426435; called by muse, mutect2, varscan2
- GJB1 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV100661289; called by muse, mutect2, varscan2
- GLIPR1 | c.481G>C p.G161R | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV99875798; called by muse, mutect2, varscan2
- GLT1D1 | c.682G>T p.G228* (on ENST00000442111 / NM_001366889.1; = p.G148* on NM_144669.3) | Nonsense Mutation (SNP) | VAF 27/96 reads (28%) | catalogued as COSV55880686, COSV55885260; called by muse, mutect2, varscan2
- GNB4 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs1222953811, COSV104372412, COSV99224408; called by muse, mutect2, varscan2
- GPR158 | c.2967C>G p.D989E | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV100894034; called by muse, mutect2, varscan2
- GZMA | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 89/109 reads (82%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV99956620; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.708); catalogued as COSV100676523; called by muse, mutect2, varscan2
- HSPA8 | c.1616A>T p.K539M | Missense Mutation (SNP) | VAF 98/260 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV57085441, COSV99914529; called by muse, mutect2, varscan2
- HTR1E | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 27/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100541202, COSV59508949; called by muse, mutect2
- HUWE1 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs1347758273, COSV99473425; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.309C>A p.S103R | Missense Mutation (SNP) | VAF 76/368 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as rs1272197745; called by muse, mutect2, varscan2
- IGSF10 | c.3151A>C p.T1051P | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs922558965, COSV56790845, COSV99185153; called by muse, mutect2, varscan2
- IQCE | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV58081809; called by muse, mutect2, varscan2
- KCNH1 | c.486G>T p.R162S | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as COSV99660416; called by muse, mutect2, varscan2
- KCNH7 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.829); catalogued as COSV100036981; called by muse, mutect2, varscan2
- KIF21A | c.4130G>A p.G1377E (on ENST00000361418 / NM_001378440.1; = p.G1364E on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735554; called by muse, mutect2, varscan2
- KLHL13 | c.1369A>T p.T457S | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as COSV53249143, COSV99452186; called by muse, mutect2
- KLHL32 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV100987428; called by muse, mutect2, varscan2
- KRTAP13-2 | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.133); catalogued as COSV101299659; called by muse, mutect2, varscan2
- LRRFIP2 | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 5/87 reads (6%) | catalogued as COSV100368604; called by muse, mutect2
- LTBP2 | c.2101G>T p.V701L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100000735, COSV56205878; called by mutect2, varscan2
- MAGEB1 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100975059; called by muse, mutect2
- MAN2A2 | c.3278A>G p.N1093S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.115); catalogued as rs1453545491, COSV100847940; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3169G>A p.D1057N | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV51601505; called by muse, mutect2, varscan2
- MARCHF4 | c.327del p.L110Cfs*49 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as COSV56104526; called by mutect2, pindel, varscan2
- MED12 | c.4223C>A p.P1408H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.428); catalogued as COSV100379161; called by muse, mutect2, varscan2
- MED12L | c.4157T>C p.I1386T | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs1315050599, COSV99854053; called by muse, mutect2, varscan2
- MFHAS1 | c.262A>C p.S88R | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV99359775; called by muse, mutect2, varscan2
- MPP6 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV99757712; called by muse, varscan2
- MTMR9 | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 94/110 reads (85%) | catalogued as COSV99644455; called by muse, mutect2, varscan2
- MTUS2 | c.790del p.A264Hfs*21 | Frame Shift Del (DEL) | VAF 19/31 reads (61%) | catalogued as COSV101462155, COSV101462372; called by mutect2, pindel, varscan2
- MYLK | c.4278G>C p.E1426D | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.843); catalogued as COSV100659364; called by muse, mutect2
- MYO5A | c.4780G>C p.D1594H | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62560735; called by muse, varscan2
- NAALAD2 | c.13A>G p.R5G | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1004399621, COSV100428659; called by muse, varscan2
- NDUFB4 | c.155A>G p.N52S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99481912; called by muse, mutect2, varscan2
- NIF3L1 | c.1031G>A p.R344Q (on ENST00000409020 / NM_001369444.1; = p.R317Q on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100677555; called by muse, mutect2
- NLRC5 | c.4151T>G p.L1384R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99347840; called by muse, mutect2, varscan2
- NLRP12 | c.3089G>T p.R1030L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV100145570; called by muse, mutect2, varscan2
- NOP58 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV99970745; called by muse, mutect2, varscan2
- NRXN1 | c.200T>G p.V67G | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101278394; called by muse, mutect2, varscan2
- NTPCR | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100786730, COSV64052914; called by muse, mutect2, varscan2
- OR8D1 | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100766665, COSV100766680; called by muse, mutect2, varscan2
- ORC5 | c.1015A>T p.N339Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV99857221; called by muse, mutect2, varscan2
- OTOGL | c.1798G>T p.E600* (on ENST00000547103; = p.E591* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV101509452; called by muse, mutect2, varscan2
- PATJ | c.2810del p.P937Rfs*9 | Frame Shift Del (DEL) | VAF 56/228 reads (25%) | catalogued as rs1257256888; called by mutect2, pindel, varscan2
- PCDHGA4 | c.2146G>T p.D716Y | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV99542941; called by muse, mutect2, varscan2
- PCDHGA8 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV53949255; called by muse, mutect2, varscan2
- PCTP | c.422C>G p.P141R | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV99273860; called by muse, mutect2, varscan2
- PDCD1 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.75); catalogued as COSV100545497; called by muse, mutect2, varscan2
- PIK3CG | c.1139C>G p.T380R | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as COSV100783036, COSV63255830; called by muse, mutect2, varscan2
- PLEKHO2 | c.858G>C p.E286D | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.104); catalogued as COSV100060861; called by muse, mutect2
- PLOD2 | c.1837A>T p.M613L | Missense Mutation (SNP) | VAF 74/283 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV99283065; called by muse, mutect2, varscan2
- PNPLA7 | c.3783G>C p.Q1261H | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.139); catalogued as COSV99481140; called by muse, mutect2, varscan2
- POLQ | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV99952601; called by muse, mutect2, varscan2
- PPP2R2C | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV100065909, COSV100067021; called by muse, mutect2, varscan2
- PSG9 | c.112A>C p.I38L | Missense Mutation (SNP) | VAF 11/350 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99392470; called by muse, mutect2
- PTPRD | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 74/335 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61932719; called by muse, mutect2, varscan2
- PYGM | c.920A>G p.D307G | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99377407; called by muse, mutect2, varscan2
- RBM10 | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV100238090; called by muse, varscan2
- RHOXF1 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99483883; called by muse, mutect2, varscan2
- RIMS1 | c.3199A>G p.I1067V | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1218764769, COSV99328911; called by mutect2, varscan2
- RPGR | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 55/154 reads (36%) | catalogued as COSV100140252, COSV58836251; called by muse, mutect2, varscan2
- RPL10L | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs779935712, COSV100022659; called by muse, mutect2, varscan2
- RYR1 | c.6701G>C p.R2234P | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616462, COSV62112283; called by muse, mutect2, varscan2
- RYR2 | c.8891C>A p.A2964E | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.451); catalogued as COSV100772041; called by muse, mutect2, varscan2
- SAGE1 | c.2620A>T p.K874* | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as rs782732879, COSV100187650; called by muse, mutect2
- SEC31A | c.3367T>A p.F1123I (on ENST00000355196 / NM_001318120.1; = p.F1084I on NM_016211.4) | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100022157; called by muse, mutect2, varscan2
- SEL1L3 | c.550A>G p.R184G | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99340839; called by muse, mutect2, varscan2
- SELP | c.1084G>C p.G362R | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99740632; called by muse, mutect2, varscan2
- SERPINB4 | c.161G>T p.S54I | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100345870, COSV61985322; called by muse, mutect2, varscan2
- SH3TC2 | c.1290G>C p.E430D | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV100102126, COSV100102316; called by muse, mutect2
- SHANK1 | c.2490A>T p.Q830H | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99521681; called by muse, mutect2, varscan2
- SLC30A1 | c.1402T>G p.S468A | Missense Mutation (SNP) | VAF 131/461 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100879144; called by muse, mutect2, varscan2
- SLC4A5 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100697861; called by muse, mutect2, varscan2
- SLC7A7 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99591537; called by muse, mutect2, varscan2
- SORCS1 | c.1732T>A p.W578R | Missense Mutation (SNP) | VAF 83/197 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99548562; called by muse, mutect2, varscan2
- SPATA31D1 | c.3335G>T p.S1112I | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.414); catalogued as COSV100782930; called by muse, mutect2, varscan2
- SULT1A2 | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs995826819, COSV100187286; called by muse, mutect2, varscan2
- SVEP1 | c.9953G>T p.G3318V | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99929475; called by muse, mutect2, varscan2
- TAF1A | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 64/271 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV100601041; called by muse, mutect2, varscan2
- TBC1D4 | c.2816A>C p.H939P | Missense Mutation (SNP) | VAF 120/138 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100884718; called by muse, mutect2, varscan2
- TBC1D8B | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.343); catalogued as COSV99344816; called by muse, mutect2
- TBX5 | c.441T>A p.H147Q | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.39); PolyPhen benign (0.267); catalogued as COSV100091700; called by muse, mutect2, varscan2
- TCEAL6 | c.251C>A p.P84Q | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as COSV101035892; called by muse, mutect2, varscan2
- TCHH | c.3467A>C p.E1156A | Missense Mutation (SNP) | VAF 91/183 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV100915292; called by muse, mutect2, varscan2
- TENM2 | c.2878A>G p.T960A (on ENST00000518659 / NM_001122679.2; = p.T728A on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV101319198; called by muse, mutect2
- TEX55 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0.301); catalogued as COSV55211478, COSV99817680; called by muse, mutect2, varscan2
- TFCP2L1 | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 136/353 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.651); catalogued as COSV99748507; called by muse, mutect2, varscan2
- THOC2 | c.4757A>G p.H1586R | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.95); catalogued as COSV99833823; called by muse, mutect2, varscan2
- THOC2 | c.29C>A p.A10E | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV55547289, COSV99833828; called by muse, mutect2, varscan2
- TPTE | c.1031G>C p.R344T (on ENST00000618007 / NM_199261.4; = p.R326T on NM_199259.4) | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456490474; called by muse, mutect2, varscan2
- TTC37 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 78/100 reads (78%) | catalogued as COSV100706764; called by muse, mutect2, varscan2
- TTLL4 | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99293583; called by muse, mutect2, varscan2
- UGGT1 | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99390966; called by muse, mutect2, varscan2
- USP45 | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 18/323 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57329337, COSV57330668, COSV57330843; called by muse, mutect2
- VCX | c.38A>T p.K13M | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.452); catalogued as COSV100406345; called by muse, mutect2, varscan2
- VPS35L | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV51981768; called by muse, mutect2, varscan2
- WIPI2 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99993506; called by muse, mutect2
- WNT16 | c.397C>A p.H133N (on ENST00000222462 / NM_057168.2; = p.H123N on NM_016087.2) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99743304; called by muse, mutect2, varscan2
- XIRP2 | c.2041G>C p.V681L (on ENST00000628543; = p.V856L on NM_152381.6) | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99745546; called by muse, mutect2, varscan2
- ZCCHC12 | c.554G>T p.S185I | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as COSV100038619; called by muse, mutect2, varscan2
- ZDHHC8 | c.911A>G p.D304G | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100273033; called by muse, varscan2
- ZGRF1 | c.3692A>T p.N1231I | Missense Mutation (SNP) | VAF 119/285 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100481204; called by muse, varscan2
- ZIM2 | c.796T>A p.L266M | Missense Mutation (SNP) | VAF 129/203 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV99689809; called by muse, mutect2, varscan2
- ZNF23 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 35/103 reads (34%) | catalogued as COSV100612217; called by muse, mutect2, varscan2
- ZNF516 | c.160C>G p.R54G | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101487332, COSV71587550; called by muse, mutect2, varscan2
- ZNF783 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100954275; called by mutect2, varscan2
- ZNF804A | c.2105G>T p.G702V | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as COSV100169198; called by muse, mutect2, varscan2
- BAZ2B | c.4188dup p.V1397Cfs*8 | Frame Shift Ins (INS) | VAF 43/138 reads (31%) | called by mutect2, pindel, varscan2
- OR4D2 | c.175dup p.M59Nfs*30 | Frame Shift Ins (INS) | VAF 173/222 reads (78%) | called by mutect2, varscan2
- SLCO1B3 | c.1266del p.Q422Hfs*7 | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | called by mutect2, pindel, varscan2
- SLX4 | c.495_497del p.Q166del | In Frame Del (DEL) | VAF 36/123 reads (29%) | called by mutect2, varscan2
- ZNF26 | c.1497A>T p.E499D | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AC004922.1 | c.951G>A p.T317= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as rs752395773, COSV53555559; called by muse, mutect2, varscan2
- ACTC1 | c.594T>C p.R198= | Silent (SNP) | VAF 55/102 reads (54%) | catalogued as COSV99292045; called by muse, mutect2, varscan2
- CACNA1B | c.4536C>A p.S1512= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV99498712; called by muse, mutect2, varscan2
- CASP2 | c.567G>A p.Q189= | Silent (SNP) | VAF 84/225 reads (37%) | catalogued as COSV100131177; called by muse, mutect2, varscan2
- CCNL2 | c.1530G>T p.R510= | Silent (SNP) | VAF 86/174 reads (49%) | catalogued as COSV101275704; called by muse, varscan2
- CDH7 | c.357G>T p.T119= | Silent (SNP) | VAF 91/165 reads (55%) | catalogued as rs201657602, COSV59881319, COSV59883575; called by muse, mutect2, varscan2
- CHIA | c.1236G>A p.G412= (on ENST00000343320; = p.G304= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 48/94 reads (51%) | catalogued as COSV100588578; called by muse, mutect2, varscan2
- CLPTM1 | c.336C>T p.H112= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs757264276, COSV61613307; called by muse, mutect2, varscan2
- GAK | c.3411G>T p.P1137= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as COSV58504034; called by muse, mutect2, varscan2
- GAL3ST1 | c.567C>T p.A189= | Silent (SNP) | VAF 40/221 reads (18%) | catalogued as COSV100143178; called by muse, mutect2, varscan2
- GLIS1 | c.204G>A p.L68= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV100390480; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2487C>G p.L829= | Silent (SNP) | VAF 74/344 reads (22%) | called by muse, mutect2, varscan2
- HHIPL2 | c.330G>A p.S110= | Silent (SNP) | VAF 109/204 reads (53%) | catalogued as rs775190458, COSV100596998; called by muse, mutect2, varscan2
- IMPA2 | c.474G>T p.R158= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV99302689; called by muse, mutect2, varscan2
- KCNH7 | c.222C>T p.T74= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV100036986; called by muse, mutect2, varscan2
- MAGEL2 | c.2511C>T p.V837= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as COSV58568010; called by muse, mutect2, varscan2
- MUC13 | c.1470G>A p.T490= | Silent (SNP) | VAF 29/158 reads (18%) | catalogued as rs776470626, COSV100222427; called by muse, mutect2, varscan2
- MYO5C | c.4383A>G p.E1461= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as COSV99955116; called by muse, mutect2, varscan2
- NBAS | c.4080G>C p.L1360= | Silent (SNP) | VAF 81/250 reads (32%) | catalogued as rs144401114; called by muse, mutect2, varscan2
- NPFFR1 | c.342C>G p.A114= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99524927; called by muse, mutect2
- NR2C2AP | c.246C>T p.G82= | Silent (SNP) | VAF 23/387 reads (6%) | catalogued as COSV100284569; called by muse, mutect2
- OR10G4 | c.231C>A p.P77= | Silent (SNP) | VAF 36/196 reads (18%) | catalogued as COSV100304915; called by muse, varscan2
- OR52J3 | c.129C>T p.G43= | Silent (SNP) | VAF 49/130 reads (38%) | catalogued as COSV100984907, COSV66746722; called by muse, mutect2, varscan2
- PCDHB6 | c.186C>T p.G62= | Silent (SNP) | VAF 41/159 reads (26%) | catalogued as rs1554277416, COSV50720671; called by muse, mutect2, varscan2
- PDHX | c.951A>G p.Q317= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV99927775; called by muse, mutect2, varscan2
- RET | c.3309C>A p.P1103= | Silent (SNP) | VAF 62/151 reads (41%) | catalogued as COSV100394158; called by muse, mutect2, varscan2
- SCML1 | c.357C>A p.L119= (on ENST00000380041 / NM_001037540.3; = p.L92= on NM_006746.6) | Silent (SNP) | VAF 53/172 reads (31%) | catalogued as COSV101193962; called by muse, mutect2, varscan2
- SH3BP4 | c.672C>T p.N224= | Silent (SNP) | VAF 66/184 reads (36%) | catalogued as rs1189062417, COSV60642302; called by muse, mutect2, varscan2
- SLC2A6 | c.168G>T p.L56= | Silent (SNP) | VAF 129/256 reads (50%) | catalogued as COSV100902765; called by muse, mutect2, varscan2
- SLC5A4 | c.237C>A p.I79= | Silent (SNP) | VAF 25/225 reads (11%) | catalogued as rs201777124, COSV99832057; called by muse, mutect2, varscan2
- SMS | c.378C>G p.T126= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV101048196, COSV65113759; called by muse, mutect2, varscan2
- TGFBR2 | c.774C>G p.V258= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99847670; called by muse, mutect2, varscan2
- TGFBR2 | c.879C>T p.I293= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV99847673; called by muse, mutect2, varscan2
- TRBV6-1 | c.120G>T p.L40= | Silent (SNP) | VAF 55/148 reads (37%) | called by muse, mutect2, varscan2
- TUBB2A | c.1158G>A p.T386= | Silent (SNP) | VAF 10/250 reads (4%) | catalogued as rs200677577; called by muse, mutect2
- UNC5D | c.1860C>A p.I620= | Silent (SNP) | VAF 242/283 reads (86%) | catalogued as COSV54773312, COSV99777437; called by muse, mutect2, varscan2
- USP34 | c.225A>G p.Q75= | Silent (SNP) | VAF 71/194 reads (37%) | catalogued as rs751599888, COSV101277129; called by muse, mutect2, varscan2
- PHACTR4 | c.1816+638A>G | Intron (SNP) | VAF 105/196 reads (54%) | catalogued as COSV100868479; called by muse, mutect2, varscan2
- UBTFL2 | n.298C>A | RNA (SNP) | VAF 39/101 reads (39%) | called by muse, mutect2, varscan2
